Somatic mutation profile of tumor specimen TARGET-10-PARBKG-09A (aliquot TARGET-10-PARBKG-09A-01D) from TARGET case TARGET-10-PARBKG, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.8 years (671 days).
Specimen TARGET-10-PARBKG-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c8997346-d7df-440f-ba1c-78d1ab8ed5a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARBKG-10A (Blood Derived Normal), aliquot TARGET-10-PARBKG-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c051177-2aa6-4bb7-a0f1-4b8273718ad0

The open-access MAF lists 13 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Splice Region 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH23 | c.1037C>T p.P346L | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778251205, CM102190, COSV54924653; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 21/54 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACSM2A | c.1207C>T p.P403S (on ENST00000219054; = p.P324S on NM_001308169.2) | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as rs374997353; called by muse, mutect2, varscan2
- BCO1 | c.1493C>T p.T498M | Missense Mutation (SNP) | VAF 45/81 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as rs375017107; called by muse, mutect2, varscan2
- EBP | c.517G>A p.G173R | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781964042, CM024394; called by muse, mutect2, varscan2
- IL1RAPL2 | c.834G>A p.M278I | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV61156910; called by muse, mutect2, varscan2
- RASGRF1 | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs768700693; called by muse, mutect2, varscan2
- SLC25A22 | c.778G>A p.V260I | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs766654225; called by muse, mutect2, varscan2
- GOLGA3 | c.4424G>T p.G1475V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- OR4D5 | c.518A>T p.K173M | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- SLC30A10 | c.719-7C>G | Splice Region (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2, varscan2
- KIF21A | c.3340+102G>A | Intron (SNP) | VAF 7/23 reads (30%) | catalogued as rs1458066595; called by muse, mutect2, varscan2
- MID1IP1 | c.-8C>T | 5'UTR (SNP) | VAF 22/79 reads (28%) | catalogued as rs1418786384, COSV61231178; called by muse, mutect2, varscan2
